Somatic mutation profile of tumor specimen TCGA-14-1034-02B (aliquot TCGA-14-1034-02B-01D-2280-08) from TCGA case TCGA-14-1034, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.3 years (22,029 days).
Specimen TCGA-14-1034-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95a157f8-b846-42aa-9e3f-0a6b120b9587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1034-10A (Blood Derived Normal), aliquot TCGA-14-1034-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff5c8b99-45a0-4ef4-b7a4-e35726bef117

The open-access MAF lists 83 somatic variants for this specimen: 62 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 51, Silent 21, Frame Shift Del 6, Nonsense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 34/36 reads (94%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE3 | c.860C>T p.T287M | Missense Mutation (SNP) | VAF 174/573 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs192735238, COSV53729478; called by muse, mutect2, varscan2
- ADGRG4 | c.7751C>A p.S2584Y | Missense Mutation (SNP) | VAF 233/554 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54952704; called by muse, mutect2, varscan2
- AHNAK2 | c.12121G>A p.V4041M | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); catalogued as rs774913744, COSV60911727, COSV60915794; called by muse, mutect2, varscan2
- APBA1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as rs199962660, COSV55222437; called by muse, mutect2, varscan2
- APLN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs749155361; called by muse, varscan2
- ARHGAP45 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 130/449 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1286260881, COSV57430607; called by muse, mutect2, varscan2
- ARSD | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54199043; called by muse, mutect2, varscan2
- B3GNT2 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV57344289; called by muse, mutect2, varscan2
- CACNA1S | c.5371G>A p.A1791T | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV62938250; called by muse, mutect2
- CCDC22 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs199545573, COSV59903756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP206 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV51533210; called by muse, mutect2, varscan2
- EGFR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51775191, COSV51835541; called by muse, mutect2, varscan2
- EPX | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs1386568929, COSV56595676; called by muse, mutect2, varscan2
- ERCC4 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs148933357; called by muse, mutect2, varscan2
- F13A1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs751922706, COSV53556332; called by muse, mutect2, varscan2
- GALNT8 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs375631897; called by muse, mutect2, varscan2
- GPNMB | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs369282413; called by muse, mutect2, varscan2
- GRM8 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs537365104, COSV58807793; called by muse, mutect2, varscan2
- H2BC1 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1238051800, COSV51237036; called by muse, mutect2, varscan2
- HASPIN | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV53992047; called by muse, mutect2
- HCN1 | c.1795T>C p.S599P | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1382153041, COSV57501931; called by muse, mutect2, varscan2
- KRT23 | c.471del p.F157Lfs*26 | Frame Shift Del (DEL) | VAF 47/123 reads (38%) | catalogued as COSV52928753; called by mutect2, pindel, varscan2
- LMO7 | c.1546C>T p.R516* (on ENST00000357063; = p.R246* on NM_015842.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/36 reads (89%) | catalogued as rs1374855264, COSV58532682; called by muse, mutect2, varscan2
- LRRC31 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52980193; called by muse, mutect2, varscan2
- MEAK7 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs146039021; called by muse, mutect2, varscan2
- NECAB2 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs547664063, COSV59419969; called by muse, mutect2, varscan2
- NOX4 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV54450141; called by muse, mutect2, varscan2
- OR5K4 | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV61583578; called by muse, mutect2, varscan2
- PLCG2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369516453; called by muse, mutect2, varscan2
- PPEF1 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs778812457, COSV62995430; called by muse, mutect2, varscan2
- PPP2R1B | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs367938997; called by muse, mutect2, varscan2
- RTL3 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as rs748374091, COSV58184002; called by muse, varscan2
- SAFB2 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs770444467, COSV53042986, COSV99385817; called by muse, mutect2, varscan2
- SLITRK6 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV68389785, COSV68391987; called by muse, mutect2, varscan2
- TAS2R41 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 83/213 reads (39%) | catalogued as rs376728592; called by muse, mutect2, varscan2
- TLE2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV53579078; called by muse, mutect2, varscan2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 72/83 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2, varscan2
- UBE2W | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62473881; called by muse, varscan2
- USP45 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV57328284; called by muse, mutect2, varscan2
- WDR64 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs752206627, COSV63800690; called by muse, mutect2, varscan2
- ZBED9 | c.3838G>A p.G1280R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.635); catalogued as rs140560647; called by muse, mutect2, varscan2
- ZCCHC12 | c.53T>G p.L18W | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59571245, COSV59572380; called by muse, mutect2, varscan2
- ZNF445 | c.2830C>G p.L944V | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV68538671; called by muse, mutect2, varscan2
- ZNF676 | c.457G>A p.V153I (on ENST00000650058; = p.V121I on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs376158454; called by muse, mutect2, varscan2
- ZNF780B | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.601); catalogued as COSV55463014; called by muse, mutect2, varscan2
- ZNF862 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV56223397, COSV56226467; called by muse, mutect2, varscan2
- ABCA9 | c.2664T>A p.Y888* | Nonsense Mutation (SNP) | VAF 78/184 reads (42%) | called by muse, mutect2, varscan2
- ATCAY | c.433del p.D145Tfs*13 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel*, varscan2
- BRD2 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DSC3 | c.1740_1747del p.E580Dfs*16 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- HNF1B | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC5B | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC6 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH1 | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 232/555 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PHTF1 | c.808_817del p.G270Mfs*15 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- PLA2G4C | c.1372G>T p.G458* | Nonsense Mutation (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- PLEKHH1 | c.2656G>C p.V886L | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2
- PTPN23 | c.1825del p.Y609Mfs*4 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- TOP3A | c.349_350del p.E117Nfs*2 | Frame Shift Del (DEL) | VAF 32/74 reads (43%) | called by mutect2, pindel, varscan2
- VSIG1 | c.1154T>A p.V385D | Missense Mutation (SNP) | VAF 111/252 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF674 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AIG1 | c.246C>A p.L82= | Silent (SNP) | VAF 88/96 reads (92%) | called by muse, mutect2, varscan2
- AMDHD1 | c.876C>T p.I292= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs148414685; called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs199829982; called by muse, mutect2, varscan2
- CD163 | c.2076G>A p.S692= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs374794909; called by muse, mutect2, varscan2
- CKAP5 | c.2997G>A p.L999= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV56363411; called by muse, mutect2, varscan2
- DENND1A | c.1176C>T p.G392= | Silent (SNP) | VAF 136/296 reads (46%) | catalogued as rs747557895, COSV65324124; called by muse, mutect2, varscan2
- DNAH1 | c.8019C>T p.D2673= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs759999285, COSV70227608; called by muse, mutect2, varscan2
- DNAH11 | c.3333G>A p.V1111= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1469670866, COSV60948653; called by muse, mutect2, varscan2
- KRTAP10-10 | c.162G>A p.Q54= | Silent (SNP) | VAF 74/192 reads (39%) | catalogued as COSV59956827; called by muse, mutect2, varscan2
- LIN54 | c.360A>T p.V120= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100464678; called by muse, mutect2
- PPARGC1B | c.939C>T p.P313= | Silent (SNP) | VAF 63/103 reads (61%) | catalogued as rs747264689, COSV100495022, COSV58528003; called by muse, mutect2, varscan2
- PRDM9 | c.939C>A p.A313= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV57004468; called by muse, mutect2, varscan2
- RPRD1B | c.792T>C p.N264= | Silent (SNP) | VAF 75/148 reads (51%) | called by muse, mutect2, varscan2
- SETBP1 | c.4362C>T p.R1454= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1568058620, COSV56317422; called by muse, mutect2, varscan2
- SLC9A3 | c.369C>T p.I123= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs144657077; called by muse, mutect2, varscan2
- ST8SIA3 | c.573C>T p.F191= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs376754702; called by muse, mutect2, varscan2
- SYT16 | c.1518G>A p.A506= | Silent (SNP) | VAF 88/91 reads (97%) | catalogued as rs200581957, COSV70854823; called by muse, mutect2, varscan2
- TNPO3 | c.714G>A p.S238= | Silent (SNP) | VAF 68/261 reads (26%) | catalogued as rs1338377207, COSV55281258; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRPC7 | c.240C>T p.N80= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as rs372900766, COSV61456123; called by muse, mutect2, varscan2
- TTN | c.47082C>T p.R15694= (on ENST00000591111; = p.R8270= on NM_003319.4) | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as rs940135679, COSV59965340; called by muse, mutect2, varscan2
- ZNF189 | c.1572T>A p.L524= | Silent (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
